Somatic mutation profile of tumor specimen TCGA-AA-A010-01A (aliquot TCGA-AA-A010-01A-01D-A17O-10) from TCGA case TCGA-AA-A010, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIB; Age at diagnosis: 46.3 years (16,922 days).
Specimen TCGA-AA-A010-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2615ab19-6065-42fa-9a9b-e4dc20f85376.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A010-10A (Blood Derived Normal), aliquot TCGA-AA-A010-10A-01D-A17O-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac54e017-3242-4fe7-bade-301b0bdf9fbc

The open-access MAF lists 8,856 somatic variants for this specimen: 6,854 protein-altering or splice-affecting, 1,791 silent, 211 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5,997, Silent 1,791, Nonsense Mutation 653, Splice Site 102, Intron 83, RNA 57, Splice Region 51, 3'UTR 27, Frame Shift Del 23, Frame Shift Ins 18, 5'UTR 18, 5'Flank 13.

Variants (750 of 8,856; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 72/236 reads (31%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 58/148 reads (39%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 219/576 reads (38%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, mutect2, varscan2
- ARID2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 66/192 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1424958105, COSV57595631, COSV57607050; called by muse, mutect2, varscan2
- ATM | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | hotspot (GDC flag); catalogued as rs772821016, CM030188, CS991299, COSV53725394; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP2A1 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 99/257 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121918115, CM001614, COSV62868414; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.8991T>G p.Y2997* | Nonsense Mutation (SNP) | VAF 36/133 reads (27%) | catalogued as rs397508028, CM070045, COSV66447999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1F | c.3886C>T p.R1296C | Missense Mutation (SNP) | VAF 121/193 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557106557, CM055910, CM158325, COSV100544896, COSV59902931; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.3850C>T p.R1284C | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779823379, CM120107, COSV67502170; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CRB1 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs62635654, CM992151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDAR | c.529+1G>A p.X177_splice | Splice Site (SNP) | VAF 14/41 reads (34%) | catalogued as rs1553445945, CS061276; ClinVar: pathogenic; called by muse, mutect2
- EDNRB | c.1027C>T p.R343* (on ENST00000377211 / NM_001201397.1; = p.R253* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as rs104894390, CM993141, COSV57518833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EIF2B5 | c.607C>T p.R203C (on ENST00000647909; = p.R195C on NM_003907.3) | Missense Mutation (SNP) | VAF 69/131 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994055, CM031178, COSV56603661; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.985A>G p.K329E | Missense Mutation (SNP) | VAF 53/136 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57246521; called by muse, mutect2, varscan2
- ETV6 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 19/49 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1511682, COSV56765384, COSV56765583; called by muse, mutect2, varscan2
- F9 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 32/64 reads (50%) | catalogued as rs137852261, CM940671, COSV54378604; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FZD6 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs981045005, CM132595, COSV100708516; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- GNAQ | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 49/98 reads (50%) | hotspot (GDC flag); catalogued as COSV54106777, COSV99680195; called by muse, mutect2, varscan2
- HADHA | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 55/146 reads (38%) | catalogued as rs137852775, CM983469, COSV66106265; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IRF7 | c.1267T>G p.F423V (on ENST00000397566; = p.F410V on NM_001572.5) | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs786205223, CM153535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ITGB6 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs140015315, CM142981; ClinVar: pathogenic; called by muse, varscan2
- MITF | c.646C>T p.R216* (on ENST00000448226 / NM_006722.3; = p.R110* on NM_000248.4) | Nonsense Mutation (SNP) | VAF 38/115 reads (33%) | catalogued as rs1553702006, CM132683, COSV58829776; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 33/86 reads (38%) | catalogued as rs1558666905, COSV52274084; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYO7A | c.5899C>T p.R1967* | Nonsense Mutation (SNP) | VAF 51/118 reads (43%) | catalogued as rs376764423, CM138861; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NIPBL | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 44/119 reads (37%) | catalogued as rs587783907, CM062926, COSV56941928; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NT5C2 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 35/94 reads (37%) | catalogued as rs764453448, COSV58414684; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 68/93 reads (73%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, varscan2
- PKD2 | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 17/31 reads (55%) | catalogued as rs778235410, CM012179, COSV52936442; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POU3F4 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 87/141 reads (62%) | catalogued as rs111033345, CM109199, COSV64537699; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 107/152 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RSPH3 | c.595C>T p.R199* (on ENST00000252655; = p.R57* on NM_031924.8) | Nonsense Mutation (SNP) | VAF 63/170 reads (37%) | catalogued as rs760122351, COSV51921181; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBR1 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 26/94 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs111854391, CM061221, COSV66624834; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TGFBR2 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 59/75 reads (79%) | catalogued as rs863223852, CM063204, COSV55443474; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 41/111 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TP63 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as rs900140738, COSV53196111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TPM2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs1563929454, COSV61404711; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.78181C>T p.R26061* (on ENST00000591111; = p.R18637* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 24/55 reads (44%) | catalogued as rs1559314812, COSV59879573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 65/157 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68944577, COSV68946813; called by muse, mutect2, varscan2
- A2ML1 | c.4034G>A p.R1345Q | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1388303934, COSV55285428; called by muse, mutect2
- AACS | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs552840406; called by muse, mutect2, varscan2
- AACS | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55534374; called by muse, mutect2
- AAGAB | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV56015883; called by muse, mutect2, varscan2
- AARS1 | c.1904G>T p.R635I | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55746064, COSV55748707; called by muse, mutect2, varscan2
- AARS2 | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as rs1350653756, COSV55113196; called by muse, mutect2, varscan2
- AASS | c.2563A>C p.T855P | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.633); catalogued as COSV62788770; called by muse, mutect2, varscan2
- AASS | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV62788783; called by muse, mutect2, varscan2
- AATF | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199725061; called by muse, mutect2, varscan2
- ABAT | c.941A>G p.D314G | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV51620102; called by muse, mutect2, varscan2
- ABCA10 | c.3448G>A p.V1150I | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.027); catalogued as rs755234389, COSV52218031; called by muse, mutect2, varscan2
- ABCA10 | c.1010A>C p.K337T | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as COSV52218056; called by muse, varscan2
- ABCA12 | c.6137T>C p.V2046A (on ENST00000272895 / NM_173076.3; = p.V1728A on NM_015657.3) | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV55948917; called by muse, mutect2, varscan2
- ABCA12 | c.3080G>T p.S1027I (on ENST00000272895 / NM_173076.3; = p.S709I on NM_015657.3) | Missense Mutation (SNP) | VAF 54/169 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV55948926; called by muse, mutect2, varscan2
- ABCA12 | c.719A>C p.K240T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV55948937, COSV55964636; called by muse, varscan2
- ABCA13 | c.2445A>C p.E815D | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV70025716; called by muse, mutect2, varscan2
- ABCA13 | c.8026G>T p.E2676* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as rs375142489; called by muse, mutect2, varscan2
- ABCA13 | c.12128G>A p.R4043H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs766530816, COSV71283192; called by muse, mutect2, varscan2
- ABCA5 | c.4214G>T p.S1405I | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.581); catalogued as COSV67015681; called by muse, varscan2
- ABCA5 | c.4143G>T p.Q1381H | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67015685; called by muse, varscan2
- ABCA5 | c.1666A>C p.K556Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.134); catalogued as COSV67015686; called by muse, mutect2, varscan2
- ABCA5 | c.1493G>T p.R498I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV67015688; called by muse, mutect2, varscan2
- ABCA7 | c.5196G>T p.K1732N | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV54023939; called by muse, mutect2, varscan2
- ABCA8 | c.4607A>C p.D1536A | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV52193919; called by muse, mutect2, varscan2
- ABCA8 | c.2117T>G p.L706R | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52193929; called by muse, mutect2, varscan2
- ABCA9 | c.3955G>T p.G1319C | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60620080; called by muse, mutect2, varscan2
- ABCA9 | c.1785G>T p.E595D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV60620093; called by muse, mutect2, varscan2
- ABCA9 | c.1415C>A p.S472Y | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV60620107; called by muse, mutect2, varscan2
- ABCB1 | c.1092A>C p.E364D | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as COSV55944896; called by muse, mutect2, varscan2
- ABCB11 | c.2276C>A p.S759Y | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV55585031; called by muse, mutect2, varscan2
- ABCB11 | c.1643T>G p.F548C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM067624, COSV55585046; called by muse, mutect2, varscan2
- ABCB11 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV55585060; called by muse, mutect2, varscan2
- ABCB4 | c.3749T>C p.V1250A (on ENST00000265723 / NM_018849.3; = p.V1243A on NM_000443.4) | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55931856; called by muse, mutect2, varscan2
- ABCB5 | c.1175C>A p.S392Y | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs1238145045, COSV51702857; called by muse, mutect2, varscan2
- ABCB5 | c.2412A>C p.Q804H (on ENST00000404938 / NM_001163941.2; = p.Q359H on NM_178559.6) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV51702867; called by muse, mutect2, varscan2
- ABCB8 | c.2113G>A p.E705K (on ENST00000297504 / NM_001282291.2; = p.E688K on NM_007188.5) | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as rs1325175450, COSV52502181; called by muse, mutect2, varscan2
- ABCC1 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60679996; called by muse, mutect2, varscan2
- ABCC1 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs751292519, COSV60680004; called by muse, mutect2, varscan2
- ABCC10 | c.2057T>G p.F686C (on ENST00000372530 / NM_001198934.2; = p.F658C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288961399, COSV55084286; called by muse, mutect2, varscan2
- ABCC10 | c.4148C>A p.S1383Y (on ENST00000372530 / NM_001198934.2; = p.S1355Y on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55084299; called by muse, mutect2, varscan2
- ABCC12 | c.3853G>A p.A1285T | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs771541274, COSV60911476; called by muse, mutect2, varscan2
- ABCC12 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 93/255 reads (36%) | catalogued as COSV60911484; called by muse, mutect2, varscan2
- ABCC2 | c.1579A>C p.N527H | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV64984483; called by muse, mutect2, varscan2
- ABCC2 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs574920702, COSV64984487; called by muse, varscan2
- ABCC4 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV65309555; called by muse, mutect2, varscan2
- ABCC6 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 117/374 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52741167; called by muse, mutect2, varscan2
- ABCC9 | c.4157G>A p.R1386H | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730880035, COSV53962305; ClinVar: uncertain significance; called by muse, varscan2
- ABCC9 | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs1200576081, COSV53962315; called by muse, mutect2, varscan2
- ABCC9 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs75460545, COSV53962326; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD1 | c.1024T>C p.S342P | Missense Mutation (SNP) | VAF 82/129 reads (64%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as CM950046, COSV54383395; called by muse, mutect2, varscan2
- ABCG2 | c.1957A>G p.K653E | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372911459; called by muse, mutect2, varscan2
- ABCG8 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.548); catalogued as COSV55390520; called by muse, mutect2, varscan2
- ABHD12 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV59283653; called by muse, mutect2, varscan2
- ABI3 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs771548372; called by muse, mutect2, varscan2
- ABI3BP | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV52527951; called by muse, mutect2, varscan2
- ABRAXAS1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 45/139 reads (32%) | catalogued as COSV58948039; called by muse, mutect2, varscan2
- ABRAXAS2 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 25/66 reads (38%) | catalogued as COSV53715950; called by muse, mutect2, varscan2
- ABTB1 | c.806A>T p.N269I (on ENST00000232744 / NM_172027.3; = p.N127I on NM_032548.3) | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV99229639; called by muse, mutect2, varscan2
- AC004922.1 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 135/325 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV53555442; called by muse, mutect2, varscan2
- AC011462.1 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54195456; called by muse, mutect2, varscan2
- AC134980.2 | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV60906563; called by muse, mutect2, varscan2
- ACACA | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs769240769; called by muse, mutect2, varscan2
- ACACA | c.3145G>A p.A1049T | Missense Mutation (SNP) | VAF 101/231 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs758519292; called by muse, mutect2, varscan2
- ACACB | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757955756, COSV58127896, COSV58128229; called by muse, mutect2
- ACAD9 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 98/274 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs748758547, COSV58306406; called by muse, mutect2, varscan2
- ACADM | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63719653; called by muse, mutect2, varscan2
- ACAN | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.009); catalogued as rs769858164; called by muse, mutect2, varscan2
- ACAN | c.5159C>A p.S1720Y | Missense Mutation (SNP) | VAF 96/244 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61355589; called by muse, mutect2, varscan2
- ACAP2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.91); catalogued as rs1405156868, COSV58749193; called by muse, mutect2, varscan2
- ACAT2 | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100364906, COSV58457385; called by muse, mutect2, varscan2
- ACCS | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs373138553, COSV99772928; called by muse, mutect2, varscan2
- ACCSL | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as COSV66579952; called by muse, mutect2, varscan2
- ACE2 | c.1882C>T p.L628F | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV53023553; called by muse, mutect2, varscan2
- ACMSD | c.749A>G p.D250G | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV51605451; called by muse, mutect2, varscan2
- ACP1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.536); catalogued as rs769115575, COSV55242247; called by muse, mutect2, varscan2
- ACP1 | c.356G>A p.S119N | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1396382259, COSV55242262; called by muse, mutect2, varscan2
- ACRV1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs768673984, COSV59754494; called by muse, mutect2, varscan2
- ACSBG1 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs748664490, COSV51903267, COSV99357652, COSV99357780; called by muse, mutect2, varscan2
- ACSBG1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV51903277; called by muse, mutect2, varscan2
- ACSBG1 | c.98T>A p.I33N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV51903286; called by muse, mutect2, varscan2
- ACSBG2 | c.2001A>C p.*667Cext*3 | Nonstop Mutation (SNP) | VAF 76/230 reads (33%) | catalogued as COSV53122878; called by muse, mutect2, varscan2
- ACSL3 | c.364A>C p.K122Q | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62480716; called by muse, mutect2, varscan2
- ACSL3 | c.1087A>C p.K363Q | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV62480729; called by muse, mutect2, varscan2
- ACSM1 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs146842441, COSV54632756, COSV54637011; called by muse, mutect2, varscan2
- ACSM4 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 32/94 reads (34%) | catalogued as COSV68066592; called by muse, mutect2, varscan2
- ACTL7B | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1263764064, COSV65926824; called by muse, mutect2, varscan2
- ACTL7B | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV65926826; called by muse, mutect2, varscan2
- ACTN1 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs372651589; called by muse, mutect2, varscan2
- ACTR3 | c.841A>C p.I281L | Missense Mutation (SNP) | VAF 252/693 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV54298217; called by muse, mutect2, varscan2
- ACVR1B | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765649298, COSV57774835; called by muse, mutect2, varscan2
- ACVR1B | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 30/97 reads (31%) | catalogued as COSV57779659; called by muse, varscan2
- ACVR1B | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 69/164 reads (42%) | catalogued as COSV57774850; called by muse, varscan2
- ACVR2A | c.687G>A p.W229* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as COSV54018935; called by muse, mutect2, varscan2
- ACVR2B | c.1158G>T p.M386I | Missense Mutation (SNP) | VAF 105/218 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV61701055; called by muse, mutect2, varscan2
- ADAD1 | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV56641390, COSV99635265, COSV99636245; called by muse, mutect2, varscan2
- ADAD1 | c.905A>C p.K302T | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV56641400; called by muse, mutect2, varscan2
- ADAM11 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 98/234 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52344281; called by muse, mutect2, varscan2
- ADAM12 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 54/145 reads (37%) | catalogued as COSV64102398; called by muse, mutect2, varscan2
- ADAM15 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV55056362; called by muse, mutect2, varscan2
- ADAM17 | c.1615A>G p.N539D | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV60397511; called by muse, mutect2, varscan2
- ADAM18 | c.527A>C p.K176T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV55843562; called by muse, mutect2, varscan2
- ADAM2 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.055); catalogued as rs1486484687, COSV55858669; called by muse, mutect2, varscan2
- ADAM32 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.169); catalogued as rs536001133, COSV65947053; called by muse, mutect2, varscan2
- ADAM7 | c.1210T>G p.F404V | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV51534811, COSV51537473; called by muse, mutect2, varscan2
- ADAM7 | c.1507A>G p.K503E | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.266); catalogued as COSV51534837; called by muse, varscan2
- ADAMTS1 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.886); catalogued as rs774133434; called by muse, mutect2, varscan2
- ADAMTS10 | c.2335C>T p.R779* | Nonsense Mutation (SNP) | VAF 53/163 reads (33%) | catalogued as COSV54351845; called by muse, mutect2, varscan2
- ADAMTS12 | c.4762C>T p.L1588F | Missense Mutation (SNP) | VAF 136/350 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61255253; called by muse, mutect2, varscan2
- ADAMTS12 | c.4515A>C p.K1505N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.19); catalogued as COSV61255266; called by muse, mutect2, varscan2
- ADAMTS12 | c.4159C>T p.R1387C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs771662441, COSV61254693; called by muse, mutect2, varscan2
- ADAMTS13 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs140937290, COSV63020403; called by muse, mutect2, varscan2
- ADAMTS16 | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs754871314, COSV56977587; called by muse, mutect2, varscan2
- ADAMTS17 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs765090779, COSV51472944; called by muse, mutect2, varscan2
- ADAMTS18 | c.3300G>T p.K1100N | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.628); catalogued as COSV51398577, COSV51407276; called by muse, mutect2, varscan2
- ADAMTS18 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018687209, COSV51398590; called by muse, mutect2, varscan2
- ADAMTS18 | c.642C>A p.Y214* | Nonsense Mutation (SNP) | VAF 59/161 reads (37%) | catalogued as COSV51398598, COSV51403695; called by muse, mutect2, varscan2
- ADAMTS19 | c.3470C>T p.T1157I | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1421275401, COSV50731851, COSV50749008; called by muse, mutect2, varscan2
- ADAMTS2 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1166593617; called by muse, mutect2, varscan2
- ADAMTS20 | c.2420G>T p.R807I | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67125988; called by muse, mutect2, varscan2
- ADAMTS20 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV67125989; called by muse, mutect2, varscan2
- ADAMTS3 | c.2282G>T p.G761V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104378891, COSV54384367; called by muse, mutect2, varscan2
- ADAMTS4 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs546291574, COSV63487258; called by muse, mutect2, varscan2
- ADAMTS6 | c.1979A>C p.N660T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV66856630; called by muse, mutect2, varscan2
- ADAMTS7 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as rs199628498; called by muse, mutect2, varscan2
- ADAMTS9 | c.3230T>C p.V1077A | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV55774758; called by muse, mutect2, varscan2
- ADAMTS9 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759664813, COSV55774765; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2156C>T p.T719M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs747836852, COSV65888191; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4937C>A p.S1646Y | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV54435840, COSV54468085; called by muse, mutect2, varscan2
- ADCY10 | c.3649C>T p.R1217C | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs754372156, COSV63238479; called by muse, mutect2, varscan2
- ADCY2 | c.2228G>A p.S743N | Missense Mutation (SNP) | VAF 97/250 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV57858494, COSV57858552; called by muse, mutect2, varscan2
- ADCY4 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs937602360, COSV60251848; called by muse, mutect2, varscan2
- ADCY4 | c.1932G>T p.K644N | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV60251859; called by muse, mutect2, varscan2
- ADCY7 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202891173, COSV54264517; called by muse, mutect2, varscan2
- ADCY8 | c.522C>A p.F174L | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV53895941, COSV53903391; called by muse, mutect2, varscan2
- ADCYAP1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV52485710; called by muse, mutect2, varscan2
- ADGRA3 | c.3721G>A p.D1241N | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as rs756895556, COSV51560278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRB1 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60104202; called by mutect2, varscan2
- ADGRB3 | c.1814T>C p.L605S | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV65382152; called by muse, mutect2, varscan2
- ADGRD1 | c.89C>A p.S30* | Nonsense Mutation (SNP) | VAF 141/322 reads (44%) | catalogued as COSV55438665; called by muse, mutect2, varscan2
- ADGRE3 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.241); catalogued as COSV53728256; called by muse, mutect2, varscan2
- ADGRE3 | c.577+2T>G p.X193_splice | Splice Site (SNP) | VAF 78/224 reads (35%) | catalogued as COSV53728260; called by muse, varscan2
- ADGRE3 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 122/315 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as COSV53728267, COSV99506430; called by muse, varscan2
- ADGRE5 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs372889912; called by muse, varscan2
- ADGRF2 | c.898G>T p.D300Y (on ENST00000296862 / NM_001368115.2; = p.D232Y on NM_153839.7) | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV57286377, COSV57287603; called by muse, mutect2, varscan2
- ADGRG5 | c.1491C>A p.F497L | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV61082555; called by muse, mutect2, varscan2
- ADGRG6 | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1288909399, COSV51586186; called by muse, mutect2, varscan2
- ADGRG7 | c.2083G>T p.D695Y | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56293535; called by muse, mutect2, varscan2
- ADGRG7 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs909433668, COSV56293550; called by muse, mutect2, varscan2
- ADGRL2 | c.1402T>C p.F468L | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.314); catalogued as COSV54651461; called by muse, mutect2, varscan2
- ADGRL2 | c.4177G>A p.D1393N (on ENST00000370717 / NM_001366005.1; = p.D1337N on NM_012302.4) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as COSV54651510; called by muse, mutect2, varscan2
- ADGRL3 | c.2156T>G p.L719W (on ENST00000506720 / NM_001322402.2; = p.L651W on NM_015236.6) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV72229223; called by muse, mutect2, varscan2
- ADGRL3 | c.3752G>A p.R1251Q (on ENST00000506720 / NM_001322402.2; = p.R1183Q on NM_015236.6) | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189094336, COSV72229226; called by muse, mutect2, varscan2
- ADGRL4 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs369699141; called by muse, mutect2, varscan2
- ADGRV1 | c.5944dup p.S1982Ffs*2 | Frame Shift Ins (INS) | VAF 23/99 reads (23%) | catalogued as rs1554081619; called by mutect2, pindel, varscan2
- ADGRV1 | c.12424C>T p.R4142W | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs534226753, COSV67978187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.17083C>A p.L5695I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67978194; called by muse, mutect2, varscan2
- ADH6 | c.441C>A p.F147L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52954910, COSV52956812; called by muse, mutect2, varscan2
- ADH6 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV52954921; called by muse, mutect2, varscan2
- ADH7 | c.146T>G p.V49G | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52919619; called by muse, mutect2, varscan2
- ADK | c.564del p.T190Qfs*8 (on ENST00000286621; = p.T173Qfs*8 on NM_001123.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 66/223 reads (30%) | catalogued as rs771117099; called by mutect2, pindel, varscan2
- ADORA1 | c.555C>A p.F185L | Missense Mutation (SNP) | VAF 104/314 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV55141209; called by muse, mutect2, varscan2
- ADORA1 | c.800G>T p.S267I | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV55141213; called by muse, mutect2, varscan2
- ADPRM | c.822C>A p.F274L | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.649); catalogued as COSV59378924; called by muse, mutect2, varscan2
- ADRA1A | c.929T>C p.I310T | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV52356660; called by muse, varscan2
- ADRB2 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 108/258 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100019278; called by muse, varscan2
- ADSL | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs775646855, COSV53406568; called by muse, mutect2, varscan2
- ADTRP | c.139A>C p.T47P | Missense Mutation (SNP) | VAF 138/417 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57641711; called by muse, mutect2, varscan2
- AFAP1 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV61793157; called by muse, mutect2, varscan2
- AFAP1L1 | c.1111C>A p.H371N | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57043742; called by muse, mutect2, varscan2
- AFF2 | c.3644C>A p.S1215Y | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as COSV53975993; called by muse, mutect2, varscan2
- AFF3 | c.2015C>T p.S672F | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57839877; called by muse, mutect2, varscan2
- AFG1L | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs185227588, COSV64554670; called by muse, mutect2, varscan2
- AFTPH | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 46/121 reads (38%) | catalogued as COSV53215752; called by muse, mutect2, varscan2
- AGBL2 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV54089922; called by muse, mutect2, varscan2
- AGFG1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as rs142029380; called by muse, mutect2, varscan2
- AGL | c.2089G>A p.G697S | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771211030, COSV54047858; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGMO | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 36/90 reads (40%) | catalogued as COSV61105489, COSV61123901; called by muse, mutect2, varscan2
- AGMO | c.578A>C p.N193T | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61105493; called by muse, mutect2, varscan2
- AGO1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 123/292 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs748561732, COSV64594648; called by muse, mutect2, varscan2
- AGPS | c.990G>T p.E330D | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV51560805; called by muse, mutect2, varscan2
- AGRN | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 68/188 reads (36%) | catalogued as COSV101038600; called by muse, mutect2, varscan2
- AGTR1 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 86/234 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.385); catalogued as COSV62557251; called by muse, mutect2, varscan2
- AGXT2 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV51483789; called by muse, mutect2, varscan2
- AGXT2 | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV51483798; called by muse, mutect2, varscan2
- AHCTF1 | c.5696T>G p.V1899G (on ENST00000366508; = p.V1873G on NM_015446.5) | Missense Mutation (SNP) | VAF 121/335 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV58245662; called by muse, mutect2, varscan2
- AHCY | c.1094A>G p.Q365R | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV54152406; called by muse, mutect2, varscan2
- AHCYL2 | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV61485003; called by muse, varscan2
- AHNAK | c.12325G>T p.E4109* | Nonsense Mutation (SNP) | VAF 34/111 reads (31%) | catalogued as COSV57203346; called by muse, mutect2, varscan2
- AHNAK | c.10567G>A p.E3523K | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV57203356; called by muse, mutect2, varscan2
- AHNAK | c.6703C>A p.H2235N | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.295); catalogued as COSV57202894; called by muse, mutect2, varscan2
- AHNAK2 | c.11398G>T p.D3800Y | Missense Mutation (SNP) | VAF 150/404 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV60907334; called by muse, mutect2
- AHNAK2 | c.10651G>A p.G3551S | Missense Mutation (SNP) | VAF 74/271 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs199591478; called by muse, mutect2, varscan2
- AHNAK2 | c.4097C>A p.S1366Y | Missense Mutation (SNP) | VAF 174/223 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV60932360; called by muse, mutect2, varscan2
- AHNAK2 | c.3087G>T p.E1029D | Missense Mutation (SNP) | VAF 74/209 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV60907371; called by muse, mutect2, varscan2
- AHR | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs533269895, COSV54121537, COSV99619757; called by muse, mutect2, varscan2
- AICDA | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57563422, COSV57566722; called by muse, mutect2, varscan2
- AIG1 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.088); catalogued as COSV51621934; called by muse, mutect2, varscan2
- AIM2 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 58/168 reads (35%) | catalogued as COSV63698147; called by muse, mutect2, varscan2
- AIPL1 | c.973A>G p.N325D | Missense Mutation (SNP) | VAF 111/292 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV51505820; called by muse, mutect2, varscan2
- AIRE | c.135G>T p.E45D | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99381085; called by muse, mutect2, varscan2
- AJAP1 | c.857T>C p.I286T | Missense Mutation (SNP) | VAF 104/269 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100981607, COSV65448818; called by muse, mutect2, varscan2
- AJAP1 | c.1091C>A p.S364Y | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV65448822; called by muse, mutect2, varscan2
- AK3 | c.359T>G p.V120G | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV63346836; called by muse, mutect2, varscan2
- AK5 | c.1262G>T p.R421I (on ENST00000354567 / NM_174858.3; = p.R395I on NM_012093.4) | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60967389; called by muse, mutect2, varscan2
- AK7 | c.531T>G p.D177E | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV50869187; called by muse, mutect2, varscan2
- AKAP11 | c.4942G>A p.A1648T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50292502; called by muse, mutect2, varscan2
- AKAP12 | c.2570G>T p.R857M | Missense Mutation (SNP) | VAF 91/248 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV53570034; called by muse, mutect2, varscan2
- AKAP12 | c.3271G>A p.D1091N | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV53570050; called by muse, mutect2, varscan2
- AKAP12 | c.3931G>T p.E1311* | Nonsense Mutation (SNP) | VAF 42/120 reads (35%) | catalogued as COSV53574447; called by muse, varscan2
- AKAP13 | c.5127C>A p.F1709L (on ENST00000394518 / NM_007200.5; = p.F1713L on NM_006738.6) | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV63448017, COSV63455453; called by muse, varscan2
- AKAP3 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV57413597; called by muse, mutect2, varscan2
- AKAP3 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs749375251, COSV57413608, COSV99962219; called by muse, mutect2, varscan2
- AKAP5 | c.1273C>A p.L425I | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.494); catalogued as COSV57742051; called by muse, mutect2, varscan2
- AKAP6 | c.2585G>A p.R862Q | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs761876269, COSV55204580; called by muse, mutect2, varscan2
- AKAP7 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | catalogued as COSV63504692; called by muse, mutect2, varscan2
- AKAP9 | c.4670A>C p.K1557T | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.31); catalogued as COSV62338380; called by muse, mutect2, varscan2
- AKAP9 | c.5347C>T p.R1783C (on ENST00000359028; = p.R1751C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.318); catalogued as rs144269839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.8122G>T p.E2708* (on ENST00000359028; = p.E2684* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 38/112 reads (34%) | catalogued as COSV62338404; called by muse, varscan2
- AKAP9 | c.9174C>A p.F3058L (on ENST00000359028; = p.F3034L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV62338420; called by muse, mutect2, varscan2
- AKIRIN2 | c.507A>C p.E169D | Missense Mutation (SNP) | VAF 92/273 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV57635911; called by muse, mutect2, varscan2
- AKR1B15 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV71150986; called by muse, mutect2, varscan2
- AKR1C2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 76/312 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs782503043; called by muse, varscan2
- AKT3 | c.1355-1G>T p.X452_splice | Splice Site (SNP) | VAF 42/132 reads (32%) | catalogued as COSV55607126; called by muse, mutect2, varscan2
- AL121899.2 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs146616453; called by muse, mutect2, varscan2
- AL121899.2 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs767808303, COSV67349602; called by muse, mutect2, varscan2
- AL136295.1 | c.2041T>G p.F681V | Missense Mutation (SNP) | VAF 104/318 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.918); catalogued as COSV55777850; called by muse, mutect2, varscan2
- AL592490.1 | c.2249C>A p.S750Y | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1400830598, COSV69424427; called by muse, mutect2, varscan2
- AL592490.1 | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV69424436; called by muse, mutect2, varscan2
- AL645922.1 | c.1754G>A p.S585N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV54959158; called by muse, mutect2
- ALAS1 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 123/343 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59626767; called by muse, mutect2, varscan2
- ALAS1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs773336919, COSV59626776; called by muse, mutect2, varscan2
- ALDH18A1 | c.2347C>A p.L783I | Missense Mutation (SNP) | VAF 66/185 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV64662039; called by muse, mutect2, varscan2
- ALDH1A1 | c.1145T>C p.V382A | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV52789047; called by muse, mutect2, varscan2
- ALDH1A2 | c.264C>A p.F88L | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51078081; called by muse, mutect2, varscan2
- ALDH1B1 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV66619191; called by muse, mutect2, varscan2
- ALDH1B1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs779633928, COSV66619196; called by muse, mutect2, varscan2
- ALDH1B1 | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 184/453 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV66619204, COSV66620431; called by muse, mutect2, varscan2
- ALDH1L1 | c.1862G>A p.G621D | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56410518; called by muse, mutect2, varscan2
- ALDH1L1 | c.835C>A p.L279I | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.074); catalogued as COSV56416224; called by muse, mutect2, varscan2
- ALDH3A2 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 202/562 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV51565516; called by muse, varscan2
- ALDH9A1 | c.1245G>T p.E415D | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV61338943; called by muse, mutect2, varscan2
- ALG10B | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 161/399 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs1218991576, COSV100439817, COSV58142197; called by muse, mutect2, varscan2
- ALG11 | c.623C>A p.S208Y | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as CD122081, COSV73000556; called by muse, mutect2, varscan2
- ALG11 | c.926T>G p.F309C | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73000557; called by muse, mutect2, varscan2
- ALG2 | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 125/463 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53058670; called by muse, mutect2, varscan2
- ALG6 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as rs1271387707; called by muse, mutect2, varscan2
- ALG8 | c.1535T>G p.V512G | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.112); catalogued as COSV104409384, COSV55199116; called by muse, mutect2, varscan2
- ALG9 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52789460; called by muse, mutect2
- ALK | c.619G>C p.A207P | Missense Mutation (SNP) | VAF 61/168 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV66575135; called by muse, mutect2, varscan2
- ALMS1 | c.6196G>T p.D2066Y | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as COSV52502350, COSV52519674; called by muse, mutect2, varscan2
- ALMS1 | c.8576C>T p.S2859L | Missense Mutation (SNP) | VAF 74/205 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs538382027, CM156242, COSV52502380; called by muse, mutect2, varscan2
- ALMS1 | c.10574A>G p.H3525R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as COSV52502395; called by muse, mutect2, varscan2
- ALMS1 | c.11329G>A p.E3777K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs565098671, COSV52502407; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX5 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 90/193 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs560031203, COSV65550928; called by muse, mutect2, varscan2
- ALOX5AP | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs776630925, COSV100996268, COSV66857642; called by muse, mutect2, varscan2
- ALPK1 | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs768671654, COSV51581543; called by muse, mutect2, varscan2
- ALPK2 | c.5042C>T p.A1681V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs758281980, COSV64490174; called by muse, mutect2, varscan2
- ALPL | c.1526G>A p.G509D | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs79250591, COSV66375930; called by muse, mutect2, varscan2
- ALS2 | c.4125C>A p.A1375= | Splice Region (SNP) | VAF 7/22 reads (32%) | catalogued as COSV51883902; called by muse, mutect2, varscan2
- ALS2 | c.3618A>C p.K1206N | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.728); catalogued as COSV51883916; called by muse, mutect2, varscan2
- AMER1 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 133/217 reads (61%) | catalogued as COSV57654627; called by muse, mutect2, varscan2
- AMER3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs775305041, COSV100366877, COSV58465397; called by muse, mutect2, varscan2
- AMOTL1 | c.1654G>T p.E552* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV58564990; called by muse, mutect2, varscan2
- AMPD3 | c.2189G>A p.R730Q (on ENST00000396553 / NM_001025389.2; = p.R739Q on NM_000480.3) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs781765090; called by muse, varscan2
- AMPH | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57732577; called by muse, mutect2, varscan2
- AMY2A | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 66/216 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70214250; called by muse, mutect2, varscan2
- ANAPC10 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.636); catalogued as COSV58738360; called by muse, varscan2
- ANAPC10 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100518763, COSV58738370; called by muse, varscan2
- ANGPTL2 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 84/258 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52215716; called by muse, mutect2, varscan2
- ANK1 | c.615G>A p.T205= | Splice Region (SNP) | VAF 10/29 reads (34%) | catalogued as rs550448129, COSV55879780; called by muse, mutect2, varscan2
- ANK2 | c.7633G>T p.E2545* | Nonsense Mutation (SNP) | VAF 18/40 reads (45%) | catalogued as COSV52145214; called by muse, mutect2, varscan2
- ANK2 | c.10702C>T p.R3568W | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs72556376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.11259C>A p.F3753L | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.05); catalogued as COSV52145235; called by muse, mutect2, varscan2
- ANK2 | c.11786A>G p.N3929S | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); catalogued as COSV52145245; called by muse, mutect2, varscan2
- ANK3 | c.12998C>A p.S4333Y (on ENST00000280772 / NM_001320874.2; = p.S957Y on NM_001149.3) | Missense Mutation (SNP) | VAF 95/259 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); catalogued as COSV55043606, COSV55077554; called by muse, mutect2, varscan2
- ANK3 | c.11539C>A p.L3847I | Missense Mutation (SNP) | VAF 102/282 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV55043620; called by muse, mutect2, varscan2
- ANKFY1 | c.2883T>G p.N961K (on ENST00000341657 / NM_001330063.2; = p.N962K on NM_016376.5) | Missense Mutation (SNP) | VAF 162/389 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV58914440; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.847G>T p.G283C | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51840249; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4100G>A p.R1367H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757899078, COSV51840263; called by muse, mutect2, varscan2
- ANKLE2 | c.1227G>T p.K409N | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61707749; called by muse, varscan2
- ANKMY2 | c.820T>G p.F274V | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61010940; called by muse, mutect2, varscan2
- ANKRD1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65467117, COSV65468105; called by muse, mutect2, varscan2
- ANKRD1 | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63310876; called by muse, mutect2, varscan2
- ANKRD12 | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | catalogued as COSV50819073; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1883G>T p.R628I | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV62003446; called by muse, varscan2
- ANKRD26 | c.3392C>T p.S1131F | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65773911; called by muse, mutect2, varscan2
- ANKRD26 | c.3169G>T p.D1057Y | Missense Mutation (SNP) | VAF 56/126 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs969387790, COSV65773914; called by muse, mutect2, varscan2
- ANKRD28 | c.2994T>G p.N998K | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV67516829; called by muse, mutect2, varscan2
- ANKRD30A | c.389C>T p.A130V (on ENST00000611781; = p.A74V on NM_052997.2) | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64603588; called by muse, mutect2, varscan2
- ANKRD30A | c.1458T>C p.S486= (on ENST00000611781; = p.S430= on NM_052997.2) | Splice Region (SNP) | VAF 53/151 reads (35%) | catalogued as COSV64603595; called by muse, mutect2, varscan2
- ANKRD34A | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV60160244; called by muse, mutect2, varscan2
- ANKRD35 | c.2272C>T p.R758W | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV62911475; called by muse, mutect2, varscan2
- ANKRD35 | c.1862G>T p.R621I | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62909490; called by muse, mutect2, varscan2
- ANKRD35 | c.1544G>T p.R515I | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62909483; called by muse, mutect2, varscan2
- ANKRD42 | c.788T>G p.I263S | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52614297; called by muse, mutect2, varscan2
- ANKRD49 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1361548385, COSV57059778; called by muse, mutect2, varscan2
- ANKRD50 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.073); catalogued as rs377077898; called by muse, mutect2, varscan2
- ANKRD52 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57282053; called by muse, mutect2, varscan2
- ANKRD52 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1320907610, COSV57282081; called by muse, mutect2, varscan2
- ANKRD55 | c.1249C>A p.L417I | Missense Mutation (SNP) | VAF 148/494 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV61944174; called by muse, mutect2, varscan2
- ANKRD7 | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV54553773; called by muse, mutect2, varscan2
- ANKRD7 | c.574A>C p.R192= | Splice Region (SNP) | VAF 72/194 reads (37%) | catalogued as COSV54553786; called by muse, mutect2, varscan2
- ANKS1B | c.1086G>T p.K362N | Missense Mutation (SNP) | VAF 100/294 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV61334459; called by muse, mutect2, varscan2
- ANO10 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV52728301; called by muse, mutect2, varscan2
- ANO3 | c.2153A>G p.N718S | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56779976; called by muse, mutect2, varscan2
- ANO5 | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV61081900; called by muse, mutect2, varscan2
- ANO5 | c.1335G>T p.E445D | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100201535, COSV61081911; called by muse, mutect2, varscan2
- ANO5 | c.2200C>A p.L734I | Missense Mutation (SNP) | VAF 99/240 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs886042760, COSV61081922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO5 | c.2591G>T p.R864I | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV61081929; called by muse, mutect2, varscan2
- ANOS1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs199725550, COSV52915809; called by muse, mutect2, varscan2
- ANPEP | c.2434G>A p.A812T | Missense Mutation (SNP) | VAF 120/313 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs759355791, COSV55589093; called by muse, mutect2, varscan2
- ANTXR2 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 267/752 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs767242762, COSV56312614; called by muse, mutect2, varscan2
- ANXA11 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 39/99 reads (39%) | catalogued as COSV55414990; called by muse, mutect2, varscan2
- ANXA4 | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 78/205 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV67848252; called by muse, mutect2, varscan2
- ANXA6 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs34326317; called by muse, varscan2
- ANXA7 | c.991C>T p.R331C (on ENST00000372919 / NM_001320880.2; = p.R309C on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770697765, COSV65822874; called by muse, mutect2, varscan2
- ANXA8 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 164/675 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1255805570; called by muse, mutect2, varscan2
- AP000812.4 | c.23G>T p.R8I | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV53825194; called by muse, mutect2, varscan2
- AP1AR | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 50/166 reads (30%) | catalogued as COSV56768456; called by muse, varscan2
- AP2B1 | c.869C>A p.T290N | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51996898; called by muse, mutect2, varscan2
- AP3B1 | c.942+1G>A p.X314_splice | Splice Site (SNP) | VAF 34/81 reads (42%) | catalogued as COSV54876207; called by muse, mutect2, varscan2
- AP3M1 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 116/290 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV62330646; called by muse, mutect2, varscan2
- AP4B1 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as rs767747484, COSV56723146; called by muse, mutect2, varscan2
- AP4E1 | c.559A>T p.K187* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV55914940; called by muse, mutect2, varscan2
- AP4E1 | c.1029A>C p.K343N | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as COSV55914948; called by muse, mutect2, varscan2
- APAF1 | c.796G>T p.D266Y (on ENST00000551964 / NM_181861.2; = p.D255Y on NM_001160.3) | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59661498; called by muse, mutect2, varscan2
- APAF1 | c.1301G>A p.R434H (on ENST00000551964 / NM_181861.2; = p.R423H on NM_001160.3) | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs201872620, COSV59661508; called by muse, mutect2, varscan2
- APC | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57323956; called by muse, mutect2, varscan2
- APC | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57323970; called by muse, mutect2, varscan2
- APC | c.7286C>T p.S2429F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57324028; called by muse, mutect2, varscan2
- APCDD1L | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1345245430, COSV64485311; called by muse, mutect2, varscan2
- APEH | c.2095C>T p.L699F | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs1273489482, COSV56531965; called by muse, mutect2, varscan2
- APH1A | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 107/308 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1408820685; called by muse, mutect2, varscan2
- APLP2 | c.1508A>C p.D503A | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53838766; called by muse, mutect2, varscan2
- APOA4 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs142295954, COSV63360637; called by muse, mutect2, varscan2
- APOB | c.11104C>A p.L3702I | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV51922619; called by muse, mutect2, varscan2
- APOB | c.9346G>T p.G3116* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV51922643; called by muse, mutect2, varscan2
- APOB | c.6970C>A p.L2324I | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV51922652; called by muse, mutect2, varscan2
- APOB | c.4481C>T p.S1494L | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1020402380, COSV51922665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.1865C>A p.S622Y | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV51922687; called by muse, varscan2
- APOB | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 111/285 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs780841518, COSV51922701; called by muse, mutect2, varscan2
- APOBEC1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV57548150; called by muse, mutect2, varscan2
- APOBEC4 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 135/385 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs370218327, COSV58016833; called by muse, mutect2, varscan2
- APOLD1 | c.609C>A p.F203L (on ENST00000326765 / NM_001130415.2; = p.F172L on NM_030817.3) | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as COSV58731825; called by muse, mutect2, varscan2
- AQP10 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 123/305 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV61474362; called by muse, mutect2, varscan2
- AQP10 | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 75/215 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as COSV61474366; called by muse, mutect2, varscan2
- AQP9 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 58/160 reads (36%) | catalogued as rs370192849, COSV54967386; called by muse, mutect2, varscan2
- AQP9 | c.740C>A p.P247H | Missense Mutation (SNP) | VAF 154/401 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54967394; called by muse, mutect2, varscan2
- AQR | c.2714G>T p.R905I | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50030296; called by muse, mutect2, varscan2
- AQR | c.1930A>C p.N644H | Missense Mutation (SNP) | VAF 75/195 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV50029516; called by muse, mutect2, varscan2
- ARAP2 | c.2431G>T p.E811* | Nonsense Mutation (SNP) | VAF 68/208 reads (33%) | catalogued as COSV58282364; called by muse, mutect2, varscan2
- ARC | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.649); catalogued as rs771620864, COSV100751650, COSV63078381; called by muse, mutect2, varscan2
- ARF6 | c.91T>C p.Y31H | Missense Mutation (SNP) | VAF 116/288 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV53597167; called by muse, mutect2, varscan2
- ARFGAP3 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54310421; called by muse, mutect2, varscan2
- ARFGEF1 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 28/76 reads (37%) | catalogued as COSV51602242; called by muse, mutect2, varscan2
- ARG2 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746928269, COSV53619040; called by muse, mutect2, varscan2
- ARGFX | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100544072, COSV57681552; called by muse, mutect2, varscan2
- ARHGAP10 | c.353A>C p.K118T | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV60594740; called by muse, mutect2, varscan2
- ARHGAP19 | c.665A>G p.D222G | Missense Mutation (SNP) | VAF 191/519 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV57391349; called by muse, mutect2, varscan2
- ARHGAP20 | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV52806386; called by muse, mutect2, varscan2
- ARHGAP21 | c.3643G>T p.D1215Y | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57601918; called by muse, mutect2, varscan2
- ARHGAP25 | c.1410C>A p.F470L (on ENST00000409202 / NM_001007231.3; = p.F462L on NM_014882.3) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.027); catalogued as COSV54909752; called by muse, varscan2
- ARHGAP27 | c.1602C>A p.F534L (on ENST00000428638 / NM_001282290.1; = p.F193L on NM_199282.3) | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65358940; called by muse, mutect2, varscan2
- ARHGAP28 | c.1215T>G p.F405L (on ENST00000383472 / NM_001366230.1; = p.F246L on NM_001010000.3) | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51631297; called by muse, mutect2, varscan2
- ARHGAP29 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs377417799; called by muse, mutect2, varscan2
- ARHGAP29 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 40/143 reads (28%) | catalogued as COSV53108027; called by muse, mutect2, varscan2
- ARHGAP30 | c.588G>T p.E196D | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV63514787; called by muse, varscan2
- ARHGAP31 | c.1994C>A p.S665Y | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV51788945; called by muse, mutect2, varscan2
- ARHGAP32 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59843113; called by muse, mutect2, varscan2
- ARHGAP33 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 325/880 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs143998454; called by muse, mutect2, varscan2
- ARHGAP35 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 132/355 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68329135; called by muse, mutect2, varscan2
- ARHGAP35 | c.3433C>T p.R1145* | Nonsense Mutation (SNP) | VAF 46/120 reads (38%) | catalogued as COSV68329138; called by muse, mutect2, varscan2
- ARHGAP4 | c.1508G>T p.R503I | Missense Mutation (SNP) | VAF 215/337 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV63130706; called by muse, mutect2, varscan2
- ARHGEF10L | c.3460G>A p.E1154K | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.851); catalogued as rs775273646; called by muse, mutect2, varscan2
- ARHGEF12 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs1032127134, COSV63102469; called by muse, mutect2, varscan2
- ARHGEF12 | c.1749G>T p.K583N | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV63102475; called by muse, varscan2
- ARHGEF12 | c.2173G>T p.E725* | Nonsense Mutation (SNP) | VAF 31/90 reads (34%) | catalogued as COSV100754939, COSV63102481; called by muse, mutect2, varscan2
- ARHGEF12 | c.3319G>A p.A1107T | Missense Mutation (SNP) | VAF 106/288 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1339463961, COSV63102485; called by muse, mutect2, varscan2
- ARHGEF15 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775473270, COSV62724278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF26 | c.2538G>T p.K846N | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV62843723; called by muse, varscan2
- ARHGEF28 | c.2032T>C p.S678P | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV55247181; called by muse, mutect2, varscan2
- ARHGEF28 | c.3106G>T p.D1036Y | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs750588590, COSV55247202; called by muse, mutect2, varscan2
- ARHGEF28 | c.4090T>G p.F1364V | Missense Mutation (SNP) | VAF 190/490 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV55247215; called by muse, mutect2, varscan2
- ARHGEF28 | c.4289C>T p.A1430V | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1443768629, COSV55254836; called by muse, mutect2, varscan2
- ARHGEF3 | c.835A>C p.N279H | Missense Mutation (SNP) | VAF 106/283 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as COSV56323337; called by muse, mutect2, varscan2
- ARHGEF37 | c.1540A>G p.T514A | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV61367868; called by muse, mutect2, varscan2
- ARID1A | c.3667C>T p.R1223C | Missense Mutation (SNP) | VAF 128/312 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1227227387, COSV61371570; called by muse, mutect2, varscan2
- ARID4A | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV62161928; called by muse, mutect2, varscan2
- ARID4A | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 69/175 reads (39%) | catalogued as COSV62161933; called by muse, mutect2, varscan2
- ARID5B | c.3085C>T p.R1029W | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54413908, COSV54422079; called by muse, mutect2, varscan2
- ARL1 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55369862; called by muse, mutect2, varscan2
- ARL8B | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 100/304 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs766948599, COSV56577028; called by muse, mutect2, varscan2
- ARMC12 | c.657G>T p.K219N (on ENST00000373866 / NM_001286574.2; = p.K246N on NM_145028.5) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV55359123; called by muse, mutect2, varscan2
- ARMC3 | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.86); catalogued as COSV53056896; called by muse, mutect2, varscan2
- ARMC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs866196713, COSV59455677; called by muse, varscan2
- ARMC8 | c.531G>A p.G177= (on ENST00000469044 / NM_001363941.2; = p.G163= on NM_014154.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 88/288 reads (31%) | catalogued as rs957793427, COSV61767598; called by muse, mutect2, varscan2
- ARMH3 | c.2055C>A p.F685L | Missense Mutation (SNP) | VAF 107/308 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV53306271, COSV53307324, COSV53307859; called by muse, mutect2, varscan2
- ARMH4 | c.1370A>C p.D457A | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV50761520; called by muse, mutect2, varscan2
- ARNTL | c.741C>A p.F247L | Missense Mutation (SNP) | VAF 62/172 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100724735, COSV62985136; called by muse, mutect2, varscan2
- ARNTL | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100724846, COSV62985140; called by muse, mutect2, varscan2
- ARNTL2 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.736); catalogued as COSV53823278; called by muse, mutect2, varscan2
- ARPC2 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 104/273 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV55283588; called by muse, mutect2, varscan2
- ARPP21 | c.2167A>C p.M723L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV51791906; called by muse, varscan2
- ARSB | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs758641798, COSV53718888; called by muse, mutect2, varscan2
- ARSB | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.781); catalogued as COSV53718904; called by muse, mutect2, varscan2
- ART1 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV51702823; called by muse, mutect2, varscan2
- ASAH1 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as rs1352441199; called by muse, mutect2, varscan2
- ASAP2 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 50/180 reads (28%) | catalogued as COSV55627197; called by muse, mutect2, varscan2
- ASB10 | c.887G>A p.R296Q (on ENST00000420175 / NM_001142459.2; = p.R281Q on NM_080871.4) | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs1430961942, CM1514034, COSV51997831; called by muse, mutect2, varscan2
- ASB16 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 61/136 reads (45%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as rs368804726, COSV53234588; called by muse, mutect2, varscan2
- ASB4 | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57942806; called by muse, mutect2, varscan2
- ASB5 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 115/330 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV56668461, COSV56670474; called by muse, mutect2, varscan2
- ASH1L | c.3917G>A p.R1306Q | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs758885213, COSV64205321; called by muse, mutect2, varscan2
- ASH1L | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as rs867128307, COSV64205328; called by muse, varscan2
- ASIC2 | c.1348C>T p.L450F | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1337592623, COSV56755353; called by muse, mutect2, varscan2
- ASIC5 | c.659G>T p.R220I | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV72232493; called by muse, mutect2, varscan2
- ASPA | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1321065570, COSV53979938; called by muse, mutect2, varscan2
- ASPHD1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.048); catalogued as rs150342901, COSV58097096; called by muse, mutect2, varscan2
- ASPHD1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 133/365 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV58097098; called by muse, mutect2, varscan2
- ASPM | c.9094G>A p.A3032T | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs1429482664, COSV54124352; called by muse, mutect2, varscan2
- ASPM | c.7896G>T p.Q2632H | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54124359; called by muse, mutect2, varscan2
- ASPM | c.3983G>T p.R1328I | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV54124369; called by muse, mutect2, varscan2
- ASPRV1 | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV57227343; called by muse, mutect2, varscan2
- ASTL | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 61/162 reads (38%) | catalogued as COSV60903516; called by muse, mutect2, varscan2
- ASTN1 | c.1780C>T p.L594F | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV56061200, COSV56070061; called by muse, mutect2, varscan2
- ASTN1 | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 103/284 reads (36%) | SIFT tolerated, low confidence (0.58); PolyPhen probably damaging (0.971); catalogued as COSV56061207; called by muse, mutect2, varscan2
- ASTN2 | c.2693A>T p.Q898L (on ENST00000313400 / NM_001365069.1; = p.Q847L on NM_014010.5) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV57749928; called by muse, mutect2, varscan2
- ASXL1 | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 100/320 reads (31%) | catalogued as COSV60102942, COSV60105039; called by muse, mutect2, varscan2
- ASXL3 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52456783; called by muse, mutect2, varscan2
- ASXL3 | c.1058T>C p.F353S | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52456793, COSV52457412; called by muse, mutect2, varscan2
- ASZ1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV52911072, COSV52912082, COSV52914975; called by muse, varscan2
- ATAD2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs199506118; called by muse, varscan2
- ATAD2B | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 34/87 reads (39%) | catalogued as COSV53194985; called by muse, mutect2, varscan2
- ATAD5 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs373509661, COSV58971918; called by muse, mutect2, varscan2
- ATAD5 | c.3098G>T p.R1033I | Missense Mutation (SNP) | VAF 190/526 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1041463783, COSV58971929; called by muse, mutect2, varscan2
- ATCAY | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as COSV56654097, COSV56659076; called by muse, mutect2, varscan2
- ATCAY | c.809T>C p.I270T | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56654110; called by muse, mutect2, varscan2
- ATE1 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV56433223; called by muse, mutect2, varscan2
- ATF7IP | c.1231A>G p.N411D | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV53766088; called by muse, mutect2, varscan2
- ATG10 | c.397C>A p.H133N | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.565); catalogued as COSV56422412; called by muse, mutect2, varscan2
- ATG16L1 | c.1429C>T p.R477* (on ENST00000392017 / NM_030803.7; = p.R458* on NM_017974.4) | Nonsense Mutation (SNP) | VAF 71/184 reads (39%) | catalogued as COSV61464147, COSV61468342; called by muse, mutect2, varscan2
- ATG2B | c.3955A>G p.I1319V | Missense Mutation (SNP) | VAF 75/194 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55889374; called by muse, mutect2, varscan2
- ATL1 | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63295844; called by muse, mutect2, varscan2
- ATL2 | c.979C>A p.L327M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV60050329; called by muse, mutect2, varscan2
- ATM | c.4996G>T p.E1666* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV53725405, COSV53767865; called by muse, mutect2, varscan2
- ATM | c.6418T>G p.F2140V | Missense Mutation (SNP) | VAF 66/170 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.176); catalogued as COSV53725417; called by muse, varscan2
- ATM | c.7057C>A p.P2353T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53725426, COSV53785403; called by muse, mutect2, varscan2
- ATMIN | c.1226C>A p.S409Y | Missense Mutation (SNP) | VAF 72/197 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55145089; called by muse, mutect2, varscan2
- ATOH1 | c.931T>G p.L311V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.351); catalogued as COSV60037356; called by muse, mutect2, varscan2
- ATP10A | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148331114; called by muse, mutect2, varscan2
- ATP10D | c.266G>T p.R89I | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV56703617, COSV56706850; called by muse, mutect2, varscan2
- ATP10D | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs561130132, COSV56703624; called by muse, mutect2, varscan2
- ATP10D | c.2420C>T p.S807L | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as rs145762869; called by muse, mutect2, varscan2
- ATP10D | c.2890G>T p.E964* | Nonsense Mutation (SNP) | VAF 55/164 reads (34%) | catalogued as COSV56703647; called by muse, mutect2, varscan2
- ATP11A | c.1739C>A p.S580Y | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52109089; called by muse, mutect2, varscan2
- ATP11C | c.141A>C p.R47S | Missense Mutation (SNP) | VAF 82/125 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59559419; called by muse, mutect2, varscan2
- ATP12A | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745443085, COSV54512186; called by muse, mutect2, varscan2
- ATP12A | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs750121465, COSV54512200; called by muse, mutect2, varscan2
- ATP13A4 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs748768301, COSV55065774; called by muse, mutect2, varscan2
- ATP13A4 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs756991830, COSV55065788; called by muse, mutect2, varscan2
- ATP13A4 | c.51G>T p.E17D | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV55065799; called by muse, mutect2, varscan2
- ATP13A5 | c.2316G>T p.K772N | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.049); catalogued as COSV60865589; called by muse, mutect2, varscan2
- ATP1A2 | c.1056G>T p.K352N | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63402197; called by muse, mutect2, varscan2
- ATP1A3 | c.1450C>T p.P484S (on ENST00000545399 / NM_001256214.2; = p.P471S on NM_152296.5) | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57484959; called by muse, mutect2, varscan2
- ATP1A4 | c.756C>A p.F252L | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV100927640, COSV63625395; called by muse, mutect2, varscan2
- ATP1B1 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs902788197, COSV63178819; called by muse, mutect2, varscan2
- ATP23 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479183882, COSV55685387; called by muse, mutect2, varscan2
- ATP23 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55685396; called by muse, mutect2, varscan2
- ATP2A1 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 123/304 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV63919898; called by muse, mutect2, varscan2
- ATP2B1 | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as COSV53803693; called by muse, mutect2, varscan2
- ATP2B1 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53803704; called by muse, mutect2, varscan2
- ATP2B4 | c.160C>A p.L54I | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.112); catalogued as COSV58174232; called by muse, mutect2, varscan2
- ATP2B4 | c.1227C>A p.F409L | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV58174247; called by muse, mutect2, varscan2
- ATP4A | c.3064C>T p.R1022C | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs760879648; called by muse, mutect2, varscan2
- ATP4B | c.558C>T p.I186= | Splice Region (SNP) | VAF 178/543 reads (33%) | catalogued as rs372348110; called by muse, mutect2, varscan2
- ATP5F1A | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56359388; called by muse, mutect2, varscan2
- ATP5MC3 | c.221A>C p.K74T | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52976036; called by muse, mutect2, varscan2
- ATP5PO | c.515A>C p.K172T | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.345); catalogued as COSV51707917; called by muse, mutect2, varscan2
- ATP6AP2 | c.1039C>T p.R347* (on ENST00000378438; = p.R348* on NM_005765.3) | Nonsense Mutation (SNP) | VAF 31/50 reads (62%) | catalogued as COSV65797151; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 124/349 reads (36%) | catalogued as rs1226218405, CM023020, COSV59472433; called by muse, mutect2, varscan2
- ATP6V1B1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 105/234 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs727505222, CM990268, COSV52268223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP6V1E1 | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 86/237 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV53656904; called by muse, mutect2, varscan2
- ATP6V1G1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 160/463 reads (35%) | catalogued as COSV65013989; called by muse, mutect2, varscan2
- ATP6V1G3 | c.281G>A p.S94N | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1220595588, COSV55278171; called by muse, mutect2, varscan2
- ATP7B | c.4307A>G p.D1436G | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV54435027; called by muse, mutect2, varscan2
- ATP8A2 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV54936153; called by muse, mutect2, varscan2
- ATP8A2 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs535509828, COSV54936164, COSV99680731; called by muse, mutect2, varscan2
- ATP8A2 | c.3350C>T p.A1117V | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.024); catalogued as rs368163155; called by muse, mutect2, varscan2
- ATP8B1 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52172859; called by muse, mutect2, varscan2
- ATP8B2 | c.148C>T p.R50W (on ENST00000672630; = p.R17W on NM_001005855.2) | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1424511928, COSV59244486; called by muse, mutect2, varscan2
- ATP8B3 | c.3690G>T p.E1230D | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.366); catalogued as COSV59547680; called by muse, mutect2, varscan2
- ATR | c.4806G>T p.E1602D | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV63383724; called by muse, mutect2, varscan2
- ATR | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.106); catalogued as rs532495501, COSV63383731; called by muse, mutect2, varscan2
- ATR | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 113/310 reads (36%) | catalogued as rs1481829794, COSV63383734; called by muse, mutect2, varscan2
- ATRN | c.3952C>T p.R1318* | Nonsense Mutation (SNP) | VAF 22/50 reads (44%) | catalogued as COSV53523748; called by muse, mutect2, varscan2
- ATXN3 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 81/238 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs531719156, COSV61493627; called by muse, mutect2, varscan2
- ATXN7L2 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs753760117, COSV63992048; called by muse, mutect2, varscan2
- AUNIP | c.629G>T p.S210I | Missense Mutation (SNP) | VAF 74/194 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV65352407; called by muse, mutect2, varscan2
- AURKB | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 61/191 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1322292985, COSV60243500; called by muse, mutect2, varscan2
- AVPR1A | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 164/486 reads (34%) | catalogued as rs761842296, COSV54545596; called by muse, mutect2, varscan2
- AXDND1 | c.2790G>T p.E930D | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV62639544; called by muse, mutect2, varscan2
- AXDND1 | c.2853G>T p.E951D | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62639551; called by muse, varscan2
- AXIN2 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61055422; called by muse, mutect2, varscan2
- B2M | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 158/210 reads (75%) | catalogued as COSV62562883; called by muse, varscan2
- B3GALT5 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs1252393151, COSV58197816; called by muse, mutect2, varscan2
- B3GLCT | c.367A>G p.R123G | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.245); catalogued as COSV58453205; called by muse, mutect2, varscan2
- B4GALT1 | c.1021A>G p.I341V | Missense Mutation (SNP) | VAF 106/244 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.65); catalogued as COSV65707479; called by muse, mutect2, varscan2
- B4GALT1 | c.702A>C p.E234D | Missense Mutation (SNP) | VAF 89/214 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65707483; called by muse, mutect2, varscan2
- B4GALT2 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs755791825, COSV58842380; called by muse, mutect2, varscan2
- B4GALT2 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.363); catalogued as rs752842123, COSV58842392; called by muse, mutect2, varscan2
- B4GALT3 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as rs1369539144, COSV60526415; called by muse, mutect2, varscan2
- B4GALT6 | c.839T>G p.I280S | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV52702582; called by muse, mutect2, varscan2
- BACE2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as rs1446992945; called by muse, varscan2
- BACE2 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.569); catalogued as COSV100161237; called by muse, varscan2
- BACE2 | c.772T>G p.L258V | Missense Mutation (SNP) | VAF 116/302 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57737262; called by muse, mutect2, varscan2
- BACH1 | c.540G>T p.Q180H | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV54517243; called by muse, mutect2, varscan2
- BACH2 | c.1696C>A p.L566M | Missense Mutation (SNP) | VAF 109/269 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV57584001; called by muse, mutect2, varscan2
- BAD | c.74G>A p.S25N | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.409); catalogued as rs775688969; called by muse, mutect2, varscan2
- BAG6 | c.2783A>G p.Q928R (on ENST00000676571; = p.Q881R on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/255 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV52987818; called by muse, mutect2, varscan2
- BANK1 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV59838766; called by muse, mutect2, varscan2
- BAP1 | c.896A>G p.N299S | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56230440; called by muse, mutect2, varscan2
- BARX2 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV55649257; called by muse, mutect2, varscan2
- BAZ1A | c.749A>C p.K250T | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV62408942; called by muse, mutect2, varscan2
- BAZ2A | c.5059A>G p.N1687D | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.1); catalogued as rs757377596, COSV51631362; called by muse, mutect2, varscan2
- BAZ2A | c.4925G>A p.R1642H | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs780106566, COSV51631385, COSV51641212; called by muse, mutect2, varscan2
- BAZ2A | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 50/120 reads (42%) | catalogued as COSV51631407; called by muse, mutect2, varscan2
- BAZ2B | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as rs201823989, COSV58595520; called by muse, mutect2, varscan2
- BBOF1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58220531; called by muse, mutect2, varscan2
- BBOX1 | c.526T>G p.F176V | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as COSV54189134; called by muse, mutect2, varscan2
- BBS12 | c.983C>A p.S328Y | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58561317, COSV58561950; called by muse, mutect2, varscan2
- BBS2 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762922907, COSV55325032; called by muse, mutect2, varscan2
- BBS4 | c.1106+1G>T p.X369_splice | Splice Site (SNP) | VAF 56/128 reads (44%) | catalogued as COSV51436384; called by muse, mutect2, varscan2
- BBS7 | c.1008G>T p.Q336H | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV52654186; called by muse, mutect2
- BBS7 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV52654200; called by muse, mutect2, varscan2
- BBX | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs770138977, COSV57878573; called by muse, mutect2, varscan2
- BCAR1 | c.2295C>A p.F765L | Missense Mutation (SNP) | VAF 110/294 reads (37%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.972); catalogued as COSV99365716; called by muse, mutect2, varscan2
- BCAT1 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53907318; called by muse, mutect2, varscan2
- BCL10 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65353458; called by muse, mutect2, varscan2
- BCL11A | c.1991G>A p.R664H (on ENST00000335712 / NM_001365609.1; = p.R698H on NM_018014.4) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs757462932, COSV59624142; called by muse, mutect2, varscan2
- BCL9 | c.1170G>T p.Q390H | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.64); PolyPhen benign (0.054); catalogued as COSV52340810; called by muse, mutect2, varscan2
- BCL9 | c.1282G>T p.A428S | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV52340821; called by muse, mutect2, varscan2
- BCLAF1 | c.2660G>T p.W887L | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV50356804; called by muse, varscan2
- BCLAF1 | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.024); catalogued as COSV62143864; called by muse, mutect2, varscan2
- BCO1 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 67/187 reads (36%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs770573150, COSV50727987; called by muse, mutect2, varscan2
- BCOR | c.4639C>T p.R1547* (on ENST00000378444 / NM_001123385.2; = p.R1513* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 52/89 reads (58%) | catalogued as COSV60699371; called by muse, mutect2, varscan2
- BCORL1 | c.3199C>T p.R1067W | Missense Mutation (SNP) | VAF 119/190 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs373106469, COSV54389321; called by muse, mutect2, varscan2
- BDP1 | c.113A>G p.D38G | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs17845988; called by muse, mutect2, varscan2
- BDP1 | c.2941G>T p.D981Y | Missense Mutation (SNP) | VAF 120/322 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV62428771; called by muse, mutect2, varscan2
- BDP1 | c.3595G>T p.D1199Y | Missense Mutation (SNP) | VAF 110/267 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV62428776; called by muse, mutect2, varscan2
- BDP1 | c.5278G>T p.D1760Y | Missense Mutation (SNP) | VAF 133/344 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.146); catalogued as COSV62428782; called by muse, varscan2
- BEND5 | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 79/175 reads (45%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.994); catalogued as COSV100884141, COSV65716375; called by muse, mutect2, varscan2
- BEND7 | c.6A>C p.E2D | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV61987214; called by muse, mutect2, varscan2
- BICDL1 | c.734T>G p.I245S | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV66906922; called by muse, mutect2, varscan2
- BIN1 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1278753252, COSV52115895; called by muse, mutect2, varscan2
- BIN2 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57203545; called by muse, mutect2, varscan2
- BIRC3 | c.832A>C p.S278R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.119); catalogued as rs1180732396, COSV54814949; called by muse, mutect2, varscan2
- BIRC6 | c.2360A>C p.N787T | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV70195428; called by muse, mutect2, varscan2
- BIRC6 | c.7789G>A p.A2597T | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs368623523; called by muse, mutect2, varscan2
- BIRC6 | c.9798A>C p.K3266N | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); catalogued as COSV70195437; called by muse, mutect2, varscan2
- BIRC6 | c.13323G>T p.K4441N | Missense Mutation (SNP) | VAF 89/236 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV70195442, COSV70208181; called by muse, mutect2, varscan2
- BLID | c.263G>T p.R88I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as COSV73340095; called by muse, mutect2, varscan2
- BLM | c.1939C>A p.L647I | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV61921664; called by muse, mutect2, varscan2
- BLMH | c.1245C>A p.F415L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55584230; called by muse, mutect2, varscan2
- BLMH | c.713A>G p.K238R | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55584238; called by muse, varscan2
- BLOC1S1 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV57725112; called by muse, mutect2, varscan2
- BLOC1S6 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55034904; called by muse, mutect2, varscan2
- BLVRA | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 114/313 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs387906596, CM112102, COSV55512431; called by muse, mutect2, varscan2
- BLZF1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs138245508; called by muse, mutect2, varscan2
- BMF | c.467A>G p.Q156R | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55018602; called by muse, mutect2, varscan2
- BMP3 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1435451372, COSV51081644; called by muse, mutect2, varscan2
- BMP5 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376923719; called by muse, mutect2, varscan2
- BMPR1B | c.1174T>G p.F392V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1464900722, COSV52774638; called by muse, varscan2
- BMS1 | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV65732831; called by muse, varscan2
- BNC1 | c.2917C>T p.R973* | Nonsense Mutation (SNP) | VAF 62/170 reads (36%) | catalogued as rs749980467, COSV61756452, COSV61758671; called by muse, mutect2, varscan2
- BNC1 | c.2195C>A p.A732D | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV61756455; called by muse, mutect2, varscan2
- BNC1 | c.1854T>A p.S618R | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV61756461; called by muse, mutect2, varscan2
- BNC1 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 48/105 reads (46%) | catalogued as COSV61756465, COSV61757343; called by muse, mutect2, varscan2
- BNC2 | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs772424815, COSV66160640; called by muse, mutect2, varscan2
- BNIP5 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 52/168 reads (31%) | catalogued as COSV71325271, COSV71325897; called by muse, mutect2, varscan2
- BORCS7 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 55/109 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV54915535; called by muse, mutect2, varscan2
- BPHL | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV61318720; called by muse, mutect2, varscan2
- BPIFB1 | c.995T>A p.L332Q | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53604983; called by muse, mutect2, varscan2
- BPNT2 | c.917C>G p.A306G | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52906583; called by muse, mutect2, varscan2
- BRCA1 | c.2461G>T p.D821Y | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58783829; called by muse, mutect2, varscan2
- BRCA2 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV66447978; called by muse, mutect2, varscan2
- BRCA2 | c.3575T>G p.F1192C | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs80358606, COSV66447987; ClinVar: conflicting interpretations of pathogenicity / likely benign / benign; called by muse, mutect2, varscan2
- BRCA2 | c.9956C>A p.S3319Y | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.462); catalogued as rs778694116, COSV66336667; called by muse, mutect2, varscan2
- BRDT | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 212/546 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs761603557, COSV62863228; called by muse, varscan2
- BRF2 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.553); catalogued as rs140725525, COSV55102557; called by muse, mutect2, varscan2
- BRINP1 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 85/213 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs541291613, COSV56291761, COSV99774028; called by muse, mutect2, varscan2
- BRINP2 | c.409A>C p.N137H | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV64175147; called by muse, mutect2, varscan2
- BRINP3 | c.1901A>G p.K634R | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100819184, COSV66513164; called by muse, mutect2, varscan2
- BROX | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as COSV61798868; called by muse, mutect2, varscan2
- BRPF1 | c.2582C>T p.A861V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV57403136; called by muse, mutect2, varscan2
- BSN | c.5092C>A p.L1698I | Missense Mutation (SNP) | VAF 65/163 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as COSV56512845, COSV56516394; called by muse, mutect2, varscan2
- BSN | c.5213C>T p.S1738L | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1476028541, COSV56512854; called by muse, mutect2, varscan2
- BTAF1 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs1313990753, COSV56429702; called by muse, mutect2, varscan2
- BTAF1 | c.1034G>T p.R345I | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56429757, COSV99796027; called by muse, mutect2, varscan2
- BTBD7 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as rs1198567556, COSV100597941, COSV58283311; called by muse, mutect2, varscan2
- BTBD7 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 74/185 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780909487, COSV58283320; called by muse, mutect2, varscan2
- BTBD9 | c.1232A>G p.N411S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV58420665; called by muse, mutect2, varscan2
- BTN1A1 | c.1341C>A p.F447L | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV55066481; called by muse, mutect2, varscan2
- BTN2A2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs780217318, COSV61856569; called by muse, mutect2, varscan2
- BTNL2 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV66630147; called by muse, mutect2, varscan2
- BUB1 | c.1132A>G p.T378A | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs752483610, COSV57061138; called by muse, mutect2, varscan2
- BUD13 | c.891G>T p.K297N | Missense Mutation (SNP) | VAF 106/287 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV52766898, COSV52767913; called by muse, mutect2, varscan2
- C10orf90 | c.2007A>C p.Q669H | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52949247; called by muse, mutect2, varscan2
- C11orf71 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 59/127 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as COSV57783903; called by muse, mutect2, varscan2
- C12orf4 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 69/208 reads (33%) | catalogued as COSV54205561; called by muse, mutect2, varscan2
- C12orf4 | c.708C>A p.N236K | Missense Mutation (SNP) | VAF 112/346 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV54205569; called by mutect2, varscan2
- C14orf39 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.146); catalogued as COSV58779370; called by muse, mutect2, varscan2
- C16orf87 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 47/129 reads (36%) | catalogued as COSV53511528; called by muse, mutect2, varscan2
- C17orf75 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56752187; called by muse, mutect2, varscan2
- C1GALT1C1L | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 184/520 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs910474337, COSV56749520; called by muse, mutect2, varscan2
- C1QTNF1 | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); catalogued as COSV59260426; called by muse, mutect2, varscan2
- C1QTNF3 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 69/175 reads (39%) | catalogued as rs1173584671, COSV51467655; called by muse, mutect2, varscan2
- C1orf141 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs147612243; called by muse, mutect2, varscan2
- C1orf174 | c.594C>A p.F198L | Missense Mutation (SNP) | VAF 56/162 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64365621; called by muse, mutect2, varscan2
- C1orf189 | c.113C>A p.A38E | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63890751; called by muse, mutect2, varscan2
- C1orf194 | c.337G>T p.E113* (on ENST00000369948 / NM_001245025.3; = p.E101* on NM_001122961.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 203/525 reads (39%) | catalogued as rs763816794, COSV64049816; called by muse, mutect2, varscan2
- C1orf52 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 172/486 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs750091650, COSV53998001; called by muse, mutect2, varscan2
- C20orf194 | c.3442G>T p.D1148Y | Missense Mutation (SNP) | VAF 145/435 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52691097; called by muse, varscan2
- C20orf194 | c.3393C>A p.F1131L | Missense Mutation (SNP) | VAF 126/394 reads (32%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.979); catalogued as COSV52691108; called by muse, mutect2, varscan2
- C20orf194 | c.1632A>T p.E544D | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV52691137; called by muse, mutect2, varscan2
- C20orf194 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1219238028, COSV52691168; called by muse, mutect2, varscan2
- C22orf23 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 65/165 reads (39%) | catalogued as COSV50777637; called by muse, mutect2, varscan2
- C2CD3 | c.4356G>T p.K1452N | Missense Mutation (SNP) | VAF 114/303 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV58089347, COSV58101865; called by muse, mutect2, varscan2
- C2CD3 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs767466509, COSV100486163, COSV58089358; called by muse, mutect2, varscan2
- C2CD5 | c.2881C>A p.L961I | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV61722705; called by muse, mutect2, varscan2
- C2CD5 | c.2434T>G p.S812A | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61722712; called by muse, mutect2, varscan2
- C2CD5 | c.2333C>A p.S778Y | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV61722721; called by muse, mutect2, varscan2
- C2orf16 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV68645327, COSV68645593; called by muse, mutect2, varscan2
- C2orf16 | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 111/252 reads (44%) | catalogued as COSV62673687; called by muse, mutect2, varscan2
- C2orf16 | c.5123G>T p.R1708I | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV62673693, COSV62675606; called by muse, mutect2, varscan2
- C2orf69 | c.1022G>T p.R341I | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60665702, COSV60667349; called by muse, mutect2, varscan2
- C2orf80 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs987661802, COSV58015332; called by muse, mutect2, varscan2
- C2orf88 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61409642; called by muse, mutect2, varscan2
- C3 | c.4398C>A p.Y1466* | Nonsense Mutation (SNP) | VAF 39/127 reads (31%) | catalogued as COSV55568459; called by muse, mutect2, varscan2
- C3 | c.3490-1G>T p.X1164_splice | Splice Site (SNP) | VAF 54/144 reads (38%) | catalogued as COSV55568470; called by muse, mutect2, varscan2
- C3 | c.1758G>T p.E586D | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV55568495; called by muse, mutect2, varscan2
- C3orf20 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as rs768861528, COSV53782331, COSV99513234; called by muse, mutect2, varscan2
- C4orf50 | c.430A>G p.K144E (on ENST00000324058; = p.K1376E on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60687392; called by muse, mutect2
- C5 | c.2819C>A p.S940Y | Missense Mutation (SNP) | VAF 114/290 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV56323882; called by muse, mutect2, varscan2
- C6 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.411); catalogued as rs763257632, COSV54704717; called by muse, mutect2, varscan2
- C6 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54704728; called by muse, mutect2, varscan2
- C7orf25 | c.1199T>G p.L400R | Missense Mutation (SNP) | VAF 145/392 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63273104, COSV63274413; called by muse, mutect2, varscan2
- C8A | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); catalogued as COSV63483049; called by muse, mutect2, varscan2
- C8orf34 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61370540; called by muse, mutect2, varscan2
- C8orf34 | c.1326C>T p.F442= | Splice Region (SNP) | VAF 56/79 reads (71%) | catalogued as rs201463505, COSV57396967; called by muse, mutect2, varscan2
- C8orf34 | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV57396985; called by muse, mutect2, varscan2
- C9orf131 | c.1519C>T p.L507F | Missense Mutation (SNP) | VAF 88/214 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.965); catalogued as rs896724676, COSV56609553; called by muse, mutect2, varscan2
- C9orf43 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV55911752; called by muse, mutect2, varscan2
- C9orf43 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1356197164, COSV55911760; called by muse, mutect2, varscan2
- C9orf50 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 35/88 reads (40%) | catalogued as rs199839916, COSV65252846; called by muse, mutect2, varscan2
- C9orf64 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 121/329 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV59032087; called by muse, mutect2, varscan2
- CA11 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 112/270 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs1467562287; called by muse, mutect2, varscan2
- CA11 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 92/245 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV50032723; called by muse, mutect2, varscan2
- CA4 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs373844529; called by muse, mutect2, varscan2
- CAB39L | c.642G>T p.E214D | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV61713482; called by muse, mutect2, varscan2
- CABIN1 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54077409; called by mutect2, varscan2
- CABYR | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 49/135 reads (36%) | catalogued as COSV59110151; called by muse, mutect2, varscan2
- CACHD1 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 49/148 reads (33%) | catalogued as rs761819776, COSV51547949; called by muse, mutect2, varscan2
- CACNA1A | c.2138C>A p.A713D | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64189409; called by muse, mutect2, varscan2
- CACNA1B | c.5227C>T p.R1743C | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs370345897; called by muse, mutect2, varscan2
- CACNA1C | c.2617C>T p.P873S | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59696125; called by muse, mutect2, varscan2
- CACNA1D | c.5609G>T p.R1870I (on ENST00000350061 / NM_001128840.3; = p.R1890I on NM_000720.4) | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.024); catalogued as COSV55437170; called by muse, mutect2, varscan2
- CACNA1E | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs1458093500, COSV62398100, COSV62413841; called by muse, varscan2
- CACNA1E | c.3749A>C p.D1250A | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62381864; called by muse, mutect2, varscan2
- CACNA2D3 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 96/246 reads (39%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.85); catalogued as rs764440125, COSV55512686; called by muse, mutect2, varscan2
- CACNB3 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs758647170, COSV56397086; called by muse, mutect2, varscan2
- CACNG3 | c.793T>G p.F265V | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV50064009; called by muse, mutect2, varscan2
- CAD | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 142/362 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV53023446; called by muse, varscan2
- CAD | c.6437G>A p.R2146Q | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377103397, COSV53023457; called by muse, mutect2, varscan2
- CADM1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs758008656, COSV59002787; called by muse, mutect2, varscan2
- CADM3 | c.274G>A p.E92K (on ENST00000368125 / NM_001127173.3; = p.E126K on NM_021189.5) | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs888060211, COSV63683587; called by muse, mutect2, varscan2
- CADPS | c.2557C>A p.L853I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV51866506; called by muse, mutect2, varscan2
- CADPS | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 93/288 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51866519; called by muse, mutect2, varscan2
- CADPS | c.1004T>C p.M335T | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV51866539; called by muse, mutect2, varscan2
- CALCR | c.739G>C p.A247P (on ENST00000649521 / NM_001164737.2; = p.A231P on NM_001742.4) | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as COSV100810891, COSV64005728; called by muse, mutect2, varscan2
- CALN1 | c.372G>T p.W124C (on ENST00000329008 / NM_001017440.3; = p.W166C on NM_031468.4) | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61119278; called by muse, varscan2
- CALR3 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 103/264 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV54168331; called by muse, mutect2, varscan2
- CAMK4 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.336); catalogued as COSV56661893; called by muse, mutect2, varscan2
- CAMSAP1 | c.4635G>T p.K1545N | Missense Mutation (SNP) | VAF 321/797 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434079607, COSV56718292, COSV56721079; called by muse, mutect2, varscan2
- CAMTA2 | c.1145A>G p.N382S | Missense Mutation (SNP) | VAF 51/109 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.952); catalogued as COSV61832945; called by muse, mutect2, varscan2
- CAND1 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1389034178, COSV73389520; called by muse, mutect2, varscan2
- CAND2 | c.3308G>T p.G1103V (on ENST00000456430 / NM_001162499.2; = p.G986V on NM_012298.3) | Missense Mutation (SNP) | VAF 101/247 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV55986596; called by muse, mutect2, varscan2
- CAPN2 | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs369320951, COSV54333957; called by muse, mutect2, varscan2
- CAPN3 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.033); catalogued as rs140660066, CM990294; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN5 | c.712G>A p.D238N (on ENST00000456580; = p.D198N on NM_004055.5) | Missense Mutation (SNP) | VAF 85/247 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as rs782492041, COSV53685541; called by muse, mutect2, varscan2
- CAPRIN2 | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 9/19 reads (47%) | catalogued as COSV51830332; called by muse, mutect2, varscan2
- CAPRIN2 | c.889A>G p.T297A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV51830341; called by muse, mutect2, varscan2
- CAPSL | c.315+1G>T p.X105_splice | Splice Site (SNP) | VAF 46/126 reads (37%) | catalogued as COSV68437116; called by muse, mutect2, varscan2
- CARD6 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs199835164, COSV54564127; called by muse, mutect2, varscan2
- CARMIL1 | c.583A>C p.N195H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61513505; called by muse, mutect2, varscan2
- CARMIL1 | c.3693G>T p.K1231N | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV61513515; called by muse, mutect2, varscan2
- CARNMT1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.082); catalogued as rs1389888862, COSV65193036; called by muse, mutect2, varscan2
- CARS1 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV53449821; called by muse, mutect2, varscan2
- CASD1 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs774485536, COSV51970560; called by muse, mutect2, varscan2
- CASP10 | c.1437G>T p.K479N | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.223); catalogued as COSV51845105; called by muse, mutect2, varscan2
- CASP2 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 61/214 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs144817015, COSV100131376; called by muse, mutect2, varscan2
- CASP3 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57724572; called by muse, mutect2, varscan2
- CASP8AP2 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs753052099, COSV52745086, COSV99386833; called by muse, mutect2, varscan2
- CASP8AP2 | c.5851T>G p.F1951V | Missense Mutation (SNP) | VAF 132/356 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52745093; called by muse, mutect2, varscan2
- CASQ1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207492312, COSV63624188; called by muse, varscan2
- CATSPER3 | c.161T>G p.I54R | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.466); catalogued as COSV50945207; called by muse, mutect2, varscan2
- CATSPERB | c.3017C>T p.A1006V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV56422085; called by muse, varscan2
- CATSPERE | c.1042A>T p.R348* | Nonsense Mutation (SNP) | VAF 23/80 reads (29%) | catalogued as COSV63675766; called by muse, varscan2
- CATSPERE | c.2428A>G p.T810A | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63675772; called by muse, mutect2, varscan2
- CATSPERG | c.2557-1G>T p.X853_splice | Splice Site (SNP) | VAF 45/135 reads (33%) | catalogued as COSV53045725; called by muse, mutect2, varscan2
- CAVIN4 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as rs369545613, COSV56866500; called by muse, mutect2, varscan2
- CBL | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as rs143034856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBLN1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54653318; called by muse, mutect2, varscan2
8,106 further variants in this file (6,104 protein-altering or splice-affecting, 1,791 silent, 211 other) are not listed here.
